Somatic mutation profile of tumor specimen TARGET-20-PASYWV-09A (aliquot TARGET-20-PASYWV-09A-01D) from TARGET case TARGET-20-PASYWV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,113 days).
Specimen TARGET-20-PASYWV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42edad61-b9a4-41f4-84d8-b30dedc1d19a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYWV-14A (Bone Marrow Normal), aliquot TARGET-20-PASYWV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2455f89-5533-42d0-b7db-63bc376c3e7d

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TET2 | c.4081G>A p.G1361S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54403644, COSV54426639; called by muse, mutect2, varscan2
- CSF3R | c.2346dup p.S783Qfs*6 | Frame Shift Ins (INS) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- NF1 | c.4305C>T p.I1435= (on ENST00000358273 / NM_001042492.3; = p.I1414= on NM_000267.3) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs779865988, COSV62206764; ClinVar: likely benign; called by muse, mutect2, varscan2
